Somatic mutation profile of tumor specimen MMRF_2203_1_BM_CD138pos (aliquot MMRF_2203_1_BM_CD138pos_T1_KHS5U_L08798) from MMRF case MMRF_2203, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.7 years (21,434 days).
Specimen MMRF_2203_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c06fa994-8d4e-4c31-b469-6651f92d7bd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2203_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2203_1_PB_Whole_C3_KHS5U_L08766; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a5b280a-33d4-4f56-94b7-91c124b8f716

The open-access MAF lists 121 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 40, Missense Mutation 38, Silent 12, Intron 11, 5'UTR 6, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 3, In Frame Del 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.3587G>A p.R1196H | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs201592611; called by muse, mutect2, varscan2
- ADPRHL1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 57/65 reads (88%) | catalogued as rs774575530; called by muse, mutect2, varscan2
- APC2 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs891816905; called by muse, mutect2
- CRELD2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs753214548; called by muse, varscan2
- ERAP1 | c.2447+1G>A p.X816_splice | Splice Site (SNP) | VAF 52/148 reads (35%) | catalogued as rs568543373; called by muse, mutect2, varscan2
- FAM47B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1354190074, COSV61453613; called by muse, mutect2, varscan2
- GLI2 | c.3089C>A p.A1030E (on ENST00000361492 / NM_001374353.1; = p.A1047E on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as COSV58041688; called by muse, mutect2
- IGKV3-20 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs755087486; called by muse, mutect2, varscan2
- ITIH6 | c.2629C>A p.P877T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1457600225; called by muse, mutect2, varscan2
- LRRC71 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs913176720; called by muse, mutect2
- NLRP12 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960826983, COSV60743284, COSV60752320; called by muse, mutect2, varscan2
- PCDH15 | c.5198A>T p.N1733I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV57354954; called by muse, mutect2, varscan2
- PPP1R3A | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99492908; called by muse, mutect2, varscan2
- PPP1R3A | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764488359; called by muse, mutect2, varscan2
- SLC29A4 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs374782216; called by muse, mutect2, varscan2
- SVEP1 | c.2654T>C p.L885P | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as rs746938382; called by muse, mutect2, varscan2
- ATXN2L | c.84dup p.G29Rfs*87 | Frame Shift Ins (INS) | VAF 19/44 reads (43%) | called by mutect2, pindel, varscan2
- BPIFC | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2
- BSN | c.9634C>A p.P3212T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- C1orf94 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- CACNB1 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CCDC141 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCDC30 | c.602T>G p.V201G (on ENST00000340612; = p.V158G on NM_001080850.3) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CWC25 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.6610A>C p.N2204H | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2
- DNAJC11 | c.342A>C p.R114S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by mutect2, varscan2
- DOCK3 | c.3307A>T p.T1103S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- FBLN7 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GRIN2A | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HGF | c.1168+2T>C p.X390_splice | Splice Site (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- HOOK2 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); called by muse, mutect2
- HUWE1 | c.12751A>G p.I4251V | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- IGLV2-18 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 5/5 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by mutect2, varscan2
- KNTC1 | c.579_580del p.S194Ffs*5 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- LIPA | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- LTB | c.163-3C>A | Splice Region (SNP) | VAF 210/384 reads (55%) | called by muse, mutect2, varscan2
- MED13L | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 84/173 reads (49%) | called by muse, mutect2, varscan2
- NCOA3 | c.4264-1_4264del p.X1422_splice (on ENST00000371998 / NM_181659.3; = p.X1418_splice on NM_006534.4) | Splice Site (DEL) | VAF 76/194 reads (39%) | called by mutect2, pindel, varscan2
- NKAIN2 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRP2 | c.2080A>G p.I694V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD2 | c.3362C>G p.T1121S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH15 | c.204_210del p.D70Pfs*2 | Frame Shift Del (DEL) | VAF 31/68 reads (46%) | called by mutect2, pindel, varscan2
- PENK | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTCHD1 | c.2416A>G p.I806V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SH3PXD2B | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); called by muse, mutect2
- SIX3 | c.479A>T p.E160V | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPAG17 | c.1354del p.E452Nfs*25 | Frame Shift Del (DEL) | VAF 88/229 reads (38%) | called by mutect2, varscan2
- TENT5C | c.826_828del p.I276del | In Frame Del (DEL) | VAF 50/136 reads (37%) | called by mutect2, pindel, varscan2
- TMX1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | called by muse, mutect2, varscan2
- TNR | c.717C>G p.C239W | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2034G>A p.Q678= | Silent (SNP) | VAF 80/227 reads (35%) | called by muse, mutect2, varscan2
- ADGB | c.99A>G p.V33= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- CRAT | c.1716C>T p.D572= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs141640684; called by muse, mutect2, varscan2
- FAM117B | c.1188G>A p.T396= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs761574025, COSV57417200; called by muse, mutect2, varscan2
- IGLV3-21 | c.66G>A p.V22= | Silent (SNP) | VAF 42/43 reads (98%) | catalogued as rs558239990; called by muse, mutect2, varscan2
- IGLV3-21 | c.237A>C p.R79= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as rs538447262; called by muse, varscan2
- MICA | c.276C>T p.N92= | Silent (SNP) | VAF 16/187 reads (9%) | catalogued as rs17206561; called by muse, mutect2
- QSER1 | c.3810T>G p.T1270= (on ENST00000399302; = p.T1399= on NM_001076786.3) | Silent (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- RANBP17 | c.1890G>T p.V630= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV66657041; called by muse, mutect2, varscan2
- SERPINA12 | c.1188C>T p.S396= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs770606904, COSV57945851; called by muse, mutect2, varscan2
- XYLT1 | c.765T>A p.P255= | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- ZNF296 | c.682C>A p.R228= | Silent (SNP) | VAF 78/236 reads (33%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.-279C>T | 5'UTR (SNP) | VAF 39/119 reads (33%) | catalogued as rs1446675083; called by muse, mutect2, varscan2
- ANKRD18A | c.*247del | 3'UTR (DEL) | VAF 78/213 reads (37%) | called by mutect2, pindel, varscan2
- APCDD1L | c.*129C>A | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- ATP2B1 | c.*228A>C | 3'UTR (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- AVPR2 | c.*293G>A | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- BMPER | c.*1943C>T | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- BRD8 | c.643-537C>G | Intron (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- C10orf53 | c.*1273G>A | 3'UTR (SNP) | VAF 66/148 reads (45%) | catalogued as rs935642069; called by muse, mutect2, varscan2
- CACNA1E | c.*4173T>G | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- CCDC27 | c.554-66G>A | Intron (SNP) | VAF 19/34 reads (56%) | catalogued as rs4648404; called by muse, mutect2, varscan2
- CCN1 | c.844-17T>C | Intron (SNP) | VAF 13/148 reads (9%) | catalogued as rs377332597; called by muse, mutect2
- CHMP1B | c.*1975A>G | 3'UTR (SNP) | VAF 9/29 reads (31%) | catalogued as rs1374786330; called by muse, mutect2, varscan2
- CHMP7 | c.*767T>C | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- CTDSP2 | c.-221G>A | 5'UTR (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- CYP27B1 | c.*401C>G | 3'UTR (SNP) | VAF 36/84 reads (43%) | catalogued as rs1319212816; called by muse, mutect2, varscan2
- EIF3E | c.471+1339A>G | Intron (SNP) | VAF 33/77 reads (43%) | catalogued as rs1226724237; called by muse, mutect2, varscan2
- EPG5 | c.*3747C>T | 3'UTR (SNP) | VAF 80/166 reads (48%) | catalogued as rs1244796408; called by muse, mutect2, varscan2
- EPHA3 | c.*1922A>C | 3'UTR (SNP) | VAF 50/86 reads (58%) | called by mutect2, varscan2
- ERGIC3 | chr20:35559282 G>A | 3'Flank (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- FAM136A | c.*294C>T | 3'UTR (SNP) | VAF 97/190 reads (51%) | called by muse, mutect2, varscan2
- FANCF | c.*1351A>C | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- FBXO3 | c.*515G>T | 3'UTR (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- FZD5 | c.*4104G>A | 3'UTR (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- HSPA1B | c.-181C>G | 5'UTR (SNP) | VAF 71/149 reads (48%) | catalogued as rs572178551, COSV65148404; called by muse, mutect2
- IKZF1 | c.*842C>T | 3'UTR (SNP) | VAF 75/144 reads (52%) | called by muse, mutect2, varscan2
- IRF6 | c.*1126A>G | 3'UTR (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- KERA | c.*279T>C | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- KIF16B | c.*672C>T | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- LMAN1L | c.1451+10C>G | Intron (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- LNPK | c.*5095T>C | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- METTL4 | c.*54C>T | 3'UTR (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- MTARC1 | c.*802A>C | 3'UTR (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- NCKAP5 | c.*868T>A | 3'UTR (SNP) | VAF 50/90 reads (56%) | called by muse, mutect2, varscan2
- NFXL1 | c.2422-86A>C | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- NKAPD1 | c.320+539C>T | Intron (SNP) | VAF 5/8 reads (63%) | catalogued as rs914162746; called by muse, mutect2
- PAX8 | c.-13C>G | 5'UTR (SNP) | VAF 43/296 reads (15%) | catalogued as COSV54511832; called by muse, mutect2, varscan2
- PDGFC | c.*1155A>C | 3'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*646A>G | 3'UTR (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- RFX3 | c.*1813C>T | 3'UTR (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- RNF4 | c.*1481G>T | 3'UTR (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1533T>G | 3'UTR (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- SMAD4 | c.*307T>A | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- SSUH2 | c.608+129G>A | Intron (SNP) | VAF 20/114 reads (18%) | catalogued as rs1286287425; called by mutect2, varscan2
- SV2C | c.*1704G>T | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- TEK | c.*598G>A | 3'UTR (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- TIMP3 | c.*3196T>C | 3'UTR (SNP) | VAF 22/32 reads (69%) | called by muse, mutect2, varscan2
- TMED9 | c.*520C>T | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- TMEM182 | c.*313C>A | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- TPD52L1 | c.387-1585C>G | Intron (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- TRA2A | c.*540A>T | 3'UTR (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- TRIM27 | c.920-172T>C | Intron (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- UBE2J1 | c.-5C>G | 5'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- UHMK1 | chr1:162497814 T>C | 5'Flank (SNP) | VAF 53/143 reads (37%) | called by muse, mutect2, varscan2
- USP48 | c.3059-31T>C | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- VCAM1 | c.*438T>G | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- VEZF1 | c.-114_-100del | 5'UTR (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ZBED6 | c.*6606C>G | 3'UTR (SNP) | VAF 113/233 reads (48%) | called by muse, mutect2, varscan2
- ZBTB6 | c.*695T>A | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- ZNF585B | c.*274A>T | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
